Somatic mutation profile of tumor specimen MBCProject_0186_T1_WES (aliquot MBCProject_0186_T1_WES_1) from CMI case MBCProject_0186, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 30.5 years (11,126 days).
Specimen MBCProject_0186_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb57498-2cd1-4c8a-b4cb-4168ef3a6767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0186_SALIVA (Saliva), aliquot MBCProject_0186_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30dec964-454d-4556-9a4f-8a99ed185dda

The open-access MAF lists 90 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Intron 8, Nonsense Mutation 5, RNA 4, 3'UTR 3, In Frame Del 2, Splice Region 2, Frame Shift Del 2, Splice Site 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 54/102 reads (53%) | hotspot (GDC flag); catalogued as rs770776262, CM154128, COSV52703111, COSV52765697, COSV53067955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs190730671, COSV54963855; called by muse, mutect2, varscan2
- AHCTF1 | c.1702G>A p.D568N (on ENST00000366508; = p.D542N on NM_015446.5) | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58252455; called by muse, mutect2, varscan2
- AOAH | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99333755; called by muse, mutect2, varscan2
- BCL9 | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 132/269 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs371645881; called by muse, mutect2, varscan2
- BIRC2 | c.788A>C p.N263T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1409857425; called by muse, mutect2, varscan2
- FAM83D | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54159342; called by muse, mutect2, varscan2
- GPR149 | c.277T>C p.W93R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1395471527; called by muse, varscan2
- GREM1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV55716129; called by muse, varscan2
- LDLR | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095447; called by muse, mutect2
- LTBP4 | c.1454G>C p.R485P (on ENST00000308370 / NM_001042544.1; = p.R448P on NM_003573.2) | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs767092809; called by muse, mutect2, varscan2
- MAGEB3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs758758737; called by mutect2, varscan2
- NLRP3 | c.2920C>G p.L974V | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100275251; called by muse, mutect2, varscan2
- OTOF | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 106/375 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs768916840, COSV55500181; called by muse, mutect2, varscan2
- PCYOX1 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs759337796; called by muse, mutect2, varscan2
- SGSM2 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs767338611; called by muse, mutect2, varscan2
- SOX8 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs774000402, COSV53510473; called by muse, mutect2, varscan2
- UCP3 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as rs750818958; called by mutect2, varscan2
- XKR4 | c.1309G>C p.V437L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100530621; called by muse, mutect2, varscan2
- ACTC1 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ADAMTSL2 | c.415_441del p.D139_P147del | In Frame Del (DEL) | VAF 154/418 reads (37%) | called by mutect2, pindel, varscan2
- AKAP13 | c.7846G>T p.E2616* (on ENST00000394518 / NM_007200.5; = p.E2620* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 58/457 reads (13%) | called by muse, mutect2, varscan2
- BRD8 | c.1635_1651del p.E546Cfs*7 (on ENST00000254900 / NM_139199.2; = p.E619Cfs*7 on NM_006696.4) | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | called by mutect2, pindel
- COG1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 51/394 reads (13%) | called by muse, mutect2, varscan2
- DAP | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- DGKZ | c.2568G>T p.K856N (on ENST00000454345 / NM_001105540.2; = p.K668N on NM_003646.4) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- EGR2 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- EPPK1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ESF1 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); called by muse, mutect2
- FLNA | c.7207G>T p.D2403Y (on ENST00000369850 / NM_001110556.2; = p.D2395Y on NM_001456.3) | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FLT1 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FOXI2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- GCAT | c.311T>A p.F104Y | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GREM1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, varscan2
- GUCA1C | c.442+4A>G | Splice Region (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- HMBS | c.501G>T p.R167= | Splice Region (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- KMT2B | c.6472G>A p.D2158N | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MUCL1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBEAL2 | c.3720_3734del p.D1241_V1245del | In Frame Del (DEL) | VAF 33/142 reads (23%) | called by mutect2, pindel, varscan2
- NID2 | c.2758_2794+4del p.X920_splice | Splice Site (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel
- NPHP4 | c.1691T>C p.I564T | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.5333A>C p.D1778A (on ENST00000547103; = p.D1769A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PABPC3 | c.950T>G p.F317C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PLTP | c.837_850del p.S279Rfs*37 | Frame Shift Del (DEL) | VAF 40/388 reads (10%) | called by mutect2, pindel
- POGZ | c.2258G>T p.C753F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSMB8 | c.569G>A p.G190E (on ENST00000374882 / NM_148919.4; = p.G186E on NM_004159.5) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD18 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RPS15A | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RYR1 | c.8656T>C p.W2886R | Missense Mutation (SNP) | VAF 268/723 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC14L5 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP100 | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- TFAP2A | c.979C>G p.H327D (on ENST00000482890; = p.H319D on NM_001032280.3) | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TMEM104 | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- TMEM245 | c.2302C>G p.L768V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TTN | c.64519G>C p.V21507L (on ENST00000591111; = p.V14083L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UBE2I | c.413+1G>C p.X138_splice | Splice Site (SNP) | VAF 52/372 reads (14%) | called by muse, mutect2, varscan2
- VIPR2 | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2
- ZNF764 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZSWIM8 | c.3630G>C p.K1210N (on ENST00000605216 / NM_001242487.2; = p.K1215N on NM_015037.3) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1C | c.1164G>T p.L388= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, varscan2
- COL11A2 | c.4134C>A p.G1378= (on ENST00000341947 / NM_080680.3; = p.G1271= on NM_080679.2) | Silent (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- DNAJB5 | c.579A>C p.T193= | Silent (SNP) | VAF 111/463 reads (24%) | called by muse, mutect2, varscan2
- GFPT2 | c.1912C>T p.L638= | Silent (SNP) | VAF 68/132 reads (52%) | called by muse, mutect2, varscan2
- HYOU1 | c.1260G>T p.V420= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- LYPD3 | c.363G>C p.S121= | Silent (SNP) | VAF 34/631 reads (5%) | called by muse, mutect2
- MAGEE2 | c.1428C>A p.I476= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs1443895268, COSV64897154, COSV64897312; called by muse, mutect2, varscan2
- NLRP8 | c.582G>A p.L194= | Silent (SNP) | VAF 25/133 reads (19%) | catalogued as rs771030080; called by muse, mutect2, varscan2
- OSBPL10 | c.783C>T p.S261= | Silent (SNP) | VAF 150/584 reads (26%) | called by muse, mutect2, varscan2
- POU4F2 | c.15C>T p.S5= | Silent (SNP) | VAF 113/607 reads (19%) | catalogued as rs1224283586; called by muse, mutect2, varscan2
- PRICKLE1 | c.1440G>T p.L480= | Silent (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- WIPF3 | c.636C>A p.L212= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- ZAP70 | c.735G>T p.G245= | Silent (SNP) | VAF 66/530 reads (12%) | called by muse, mutect2, varscan2
- ZIC2 | c.291G>A p.A97= | Silent (SNP) | VAF 101/477 reads (21%) | catalogued as rs1478395009; called by muse, mutect2, varscan2
- AC090825.1 | n.493T>C | RNA (SNP) | VAF 11/117 reads (9%) | catalogued as rs1455154263; called by muse, mutect2
- AC134312.1 | n.591G>C | RNA (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- ALOX12B | c.528-10C>T | Intron (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- APP | c.1687+8638T>C | Intron (SNP) | VAF 9/75 reads (12%) | catalogued as rs1255002460; called by mutect2, varscan2
- B3GNT4 | c.*518C>A | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 24/174 reads (14%) | catalogued as rs1291738365; called by muse, mutect2
- CLMN | c.-52_-8del | 5'UTR (DEL) | VAF 46/268 reads (17%) | called by mutect2, pindel
- COL18A1 | c.*42G>C | 3'UTR (SNP) | VAF 27/249 reads (11%) | catalogued as rs369684141, COSV100229505; called by muse, mutect2, varscan2
- HMBS | c.345-37C>G | Intron (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- LINC01101 | n.170A>T | RNA (SNP) | VAF 66/491 reads (13%) | called by muse, mutect2, varscan2
- NAXE | chr1:156591766 ins GGCCGGGCCT | 5'Flank (INS) | VAF 15/44 reads (34%) | called by mutect2, varscan2
- PTMA | c.46-717_46-677del | Intron (DEL) | VAF 47/174 reads (27%) | called by mutect2, pindel
- RYR1 | c.10627-36C>A | Intron (SNP) | VAF 65/175 reads (37%) | catalogued as rs1240597250; called by muse, mutect2, varscan2
- TRIM54 | c.513+148G>A | Intron (SNP) | VAF 13/86 reads (15%) | catalogued as rs907432775; called by muse, mutect2, varscan2
- UACA | c.78+9258A>G | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs1179514522; called by mutect2, varscan2
- ZNF483 | c.*6622C>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- ZNF849P | n.444T>A | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
